Somatic mutation profile of tumor specimen C3N-02146-04 (aliquot CPT0213600009) from CPTAC case C3N-02146, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 69.7 years (25,450 days).
Specimen C3N-02146-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 35850886-274e-4a8c-8072-a36fff2418a2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02146-71 (Blood Derived Normal), aliquot CPT0213690002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d12e3555-afd9-47bc-8082-fd16f7064ea2

The open-access MAF lists 91 somatic variants for this specimen: 63 protein-altering or splice-affecting, 13 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, Silent 13, Intron 9, 5'UTR 4, Frame Shift Del 3, Splice Region 3, RNA 1, In Frame Del 1, 3'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.1161T>A p.N387K | Missense Mutation (SNP) | VAF 103/552 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868651538, COSV62688055, COSV62689041; called by muse, mutect2, varscan2
- EGFR | c.2235_2249del p.E746_A750del | In Frame Del (DEL) | VAF 86/436 reads (20%) | hotspot (GDC flag); catalogued as rs121913421, COSV51765119; ClinVar: drug response; called by mutect2, pindel, varscan2
- SMAD4 | c.1600C>T p.Q534* | Nonsense Mutation (SNP) | VAF 24/165 reads (15%) | hotspot (GDC flag); catalogued as rs377767383, CM040452, COSV61688543, COSV61692152; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AFF3 | c.2815G>A p.E939K | Missense Mutation (SNP) | VAF 19/213 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.341); catalogued as COSV104396109; called by muse, mutect2
- ATCAY | c.360C>T p.D120= | Splice Region (SNP) | VAF 55/343 reads (16%) | catalogued as rs758678492, COSV56658098; called by muse, mutect2, varscan2
- BAG3 | c.473C>T p.A158V | Missense Mutation (SNP) | VAF 46/126 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs369981590; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRCA2 | c.8525G>A p.R2842H | Missense Mutation (SNP) | VAF 27/165 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs80359105, COSV101204006; ClinVar: benign / likely benign; called by muse, mutect2, varscan2
- C3 | c.1480-8C>T | Splice Region (SNP) | VAF 16/174 reads (9%) | catalogued as rs1379608808; called by muse, mutect2
- CDR1 | c.481G>A p.G161R | Missense Mutation (SNP) | VAF 21/130 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.549); catalogued as rs761718627, COSV65163988; called by muse, mutect2, varscan2
- DBX2 | c.434C>T p.P145L | Missense Mutation (SNP) | VAF 19/287 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs1051730537, COSV60339007; called by muse, mutect2
- DCAF12L1 | c.788G>A p.R263H | Missense Mutation (SNP) | VAF 51/383 reads (13%) | SIFT tolerated (0.63); PolyPhen benign (0.005); catalogued as rs763268572, COSV64421129, COSV64421800; called by muse, mutect2, varscan2
- FLAD1 | c.680C>T p.A227V | Missense Mutation (SNP) | VAF 12/370 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1235510695; called by muse, mutect2
- GPR119 | c.802G>A p.G268S | Missense Mutation (SNP) | VAF 30/258 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs201691868; called by muse, mutect2, varscan2
- IGLON5 | c.608C>T p.S203L | Missense Mutation (SNP) | VAF 61/486 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as COSV99570735; called by muse, mutect2, varscan2
- IGLON5 | c.715G>A p.E239K | Missense Mutation (SNP) | VAF 24/324 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.646); catalogued as COSV54534245; called by muse, mutect2
- LDLRAD3 | c.449C>A p.S150Y | Missense Mutation (SNP) | VAF 40/171 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.36); catalogued as COSV59686872; called by muse, mutect2, varscan2
- MAU2 | c.1064C>T p.T355M | Missense Mutation (SNP) | VAF 39/342 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.432); catalogued as rs749804769, COSV53235618; called by muse, mutect2, varscan2
- MYO18B | c.6478G>A p.E2160K | Missense Mutation (SNP) | VAF 11/142 reads (8%) | SIFT tolerated (0.61); PolyPhen benign (0.007); catalogued as rs371851187; called by muse, mutect2
- NPC1L1 | c.3641G>A p.R1214H | Missense Mutation (SNP) | VAF 72/791 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as rs774455528, CM068038, COSV56930058; called by muse, mutect2
- OR7G3 | c.805A>G p.R269G | Missense Mutation (SNP) | VAF 36/294 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.296); catalogued as rs1411933167; called by muse, mutect2, varscan2
- PCDHA7 | c.1406C>T p.P469L | Missense Mutation (SNP) | VAF 109/730 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.895); catalogued as rs782612363, COSV100971531, COSV65348126; called by muse, mutect2, varscan2
- PITPNM3 | c.1792G>A p.V598M | Missense Mutation (SNP) | VAF 77/537 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.138); catalogued as rs530903374, COSV99339259; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PJA2 | c.790A>G p.M264V | Missense Mutation (SNP) | VAF 24/135 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs775978782; called by muse, mutect2, varscan2
- PRR14L | c.5695G>A p.E1899K | Missense Mutation (SNP) | VAF 22/208 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.129); catalogued as rs540552404, COSV57884837; called by muse, mutect2, varscan2
- RYR1 | c.4004G>A p.R1335H | Missense Mutation (SNP) | VAF 60/633 reads (9%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.718); catalogued as rs750256869, COSV62099785; ClinVar: uncertain significance; called by muse, mutect2
- SORT1 | c.11C>T p.P4L | Missense Mutation (SNP) | VAF 9/264 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1308812324; called by muse, mutect2
- USP11 | c.1874G>A p.R625H (on ENST00000218348; = p.R582H on NM_001371072.1) | Missense Mutation (SNP) | VAF 36/478 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.022); catalogued as rs1157335115, COSV54476012; called by muse, mutect2
- USP37 | c.1549C>T p.P517S | Missense Mutation (SNP) | VAF 21/128 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.223); catalogued as rs1288505463, COSV51442307; called by muse, mutect2, varscan2
- ZDBF2 | c.5471C>A p.P1824H | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100984253; called by muse, mutect2, varscan2
- ZFP62 | c.1856G>A p.C619Y (on ENST00000502412 / NM_001377944.1; = p.C586Y on NM_152283.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/257 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1333876322; called by muse, mutect2, varscan2
- ADAM19 | c.1556T>A p.L519H | Missense Mutation (SNP) | VAF 66/446 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADGRD2 | c.2462G>T p.W821L | Missense Mutation (SNP) | VAF 41/404 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- AHNAK | c.9256A>T p.I3086F | Missense Mutation (SNP) | VAF 26/496 reads (5%) | SIFT tolerated (0.54); PolyPhen benign (0.127); called by muse, mutect2
- ANKRD35 | c.862A>G p.K288E | Missense Mutation (SNP) | VAF 36/358 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- APP | c.1231A>G p.R411G | Missense Mutation (SNP) | VAF 32/368 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); called by muse, mutect2
- CDH22 | c.1655A>G p.D552G | Missense Mutation (SNP) | VAF 29/185 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- CTNNA2 | c.364A>G p.T122A | Missense Mutation (SNP) | VAF 83/350 reads (24%) | SIFT tolerated (0.95); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- DNMBP | c.2767G>A p.V923I | Missense Mutation (SNP) | VAF 100/362 reads (28%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EGFR | c.427A>C p.I143L | Missense Mutation (SNP) | VAF 70/862 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); called by muse, mutect2
- EML2 | c.1750G>A p.D584N | Missense Mutation (SNP) | VAF 40/206 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- EML2 | c.1433G>A p.G478D | Missense Mutation (SNP) | VAF 51/175 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- FBXW10 | c.2964G>T p.L988F | Missense Mutation (SNP) | VAF 61/492 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- GRIPAP1 | c.2061G>A p.R687= | Splice Region (SNP) | VAF 33/247 reads (13%) | called by muse, mutect2, varscan2
- HNRNPR | c.1760A>T p.Q587L | Missense Mutation (SNP) | VAF 76/315 reads (24%) | SIFT tolerated, low confidence (0.34); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- IGHV3-72 | c.134G>C p.G45A | Missense Mutation (SNP) | VAF 108/638 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- JADE3 | c.1516A>T p.I506F | Missense Mutation (SNP) | VAF 15/205 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); called by muse, mutect2
- LDHA | c.202G>A p.G68S | Missense Mutation (SNP) | VAF 56/506 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.626); called by muse, mutect2, varscan2
- LTBP2 | c.2014G>A p.G672R | Missense Mutation (SNP) | VAF 20/630 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- MBL2 | c.202G>A p.G68S | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NR4A1 | c.1582C>A p.Q528K | Missense Mutation (SNP) | VAF 27/150 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.595); called by muse, mutect2, varscan2
- PHKA2 | c.2890T>C p.F964L | Missense Mutation (SNP) | VAF 16/464 reads (3%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.751); called by muse, mutect2
- PIH1D2 | c.694A>T p.M232L | Missense Mutation (SNP) | VAF 24/516 reads (5%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2
- PTPRO | c.3430G>C p.G1144R (on ENST00000281171 / NM_030667.3; = p.G1116R on NM_002848.4) | Missense Mutation (SNP) | VAF 61/567 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTPRO | c.3431G>T p.G1144V (on ENST00000281171 / NM_030667.3; = p.G1116V on NM_002848.4) | Missense Mutation (SNP) | VAF 62/569 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SHANK1 | c.961G>T p.A321S | Missense Mutation (SNP) | VAF 34/274 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- SPATA31A1 | c.872G>T p.C291F | Missense Mutation (SNP) | VAF 218/968 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- SULF1 | c.1560T>A p.S520R | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT tolerated (0.59); PolyPhen benign (0.074); called by muse, mutect2
- TAOK2 | c.1655del p.K552Rfs*43 | Frame Shift Del (DEL) | VAF 52/275 reads (19%) | called by mutect2, pindel, varscan2
- TEX15 | c.6112G>C p.E2038Q (on ENST00000256246; = p.E2421Q on NM_001350162.2) | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- TNFRSF1B | c.982del p.S328Afs*58 | Frame Shift Del (DEL) | VAF 67/687 reads (10%) | called by mutect2, pindel, varscan2
- TNRC6B | c.1752C>G p.D584E | Missense Mutation (SNP) | VAF 30/330 reads (9%) | SIFT tolerated (0.79); PolyPhen probably damaging (0.97); called by muse, mutect2
- TOP2B | c.4451_4454del p.T1484Ifs*8 (on ENST00000264331 / NM_001330700.2; = p.T1479Ifs*8 on NM_001068.3) | Frame Shift Del (DEL) | VAF 12/104 reads (12%) | called by pindel, varscan2
- UHRF1BP1 | c.1289C>T p.A430V | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- ADAMTS17 | c.999G>A p.P333= | Silent (SNP) | VAF 44/349 reads (13%) | catalogued as rs748016228, COSV51491873, COSV99170690; called by muse, mutect2, varscan2
- ATP10B | c.1558C>A p.R520= | Silent (SNP) | VAF 12/211 reads (6%) | catalogued as COSV58779592; called by muse, mutect2
- COL14A1 | c.2664C>T p.N888= | Silent (SNP) | VAF 77/1266 reads (6%) | called by muse, mutect2
- HTR3A | c.429C>T p.G143= | Silent (SNP) | VAF 72/597 reads (12%) | catalogued as rs573001897, COSV55468053; called by muse, mutect2, varscan2
- JAKMIP3 | c.525G>A p.V175= | Silent (SNP) | VAF 68/581 reads (12%) | called by muse, mutect2, varscan2
- LILRA6 | c.39G>A p.L13= | Silent (SNP) | VAF 111/461 reads (24%) | called by muse, mutect2, varscan2
- MYH3 | c.4932C>A p.L1644= | Silent (SNP) | VAF 76/429 reads (18%) | called by muse, mutect2, varscan2
- OR14A16 | c.111G>A p.L37= | Silent (SNP) | VAF 8/194 reads (4%) | catalogued as COSV62926524; called by muse, mutect2
- POLE | c.6051C>T p.R2017= | Silent (SNP) | VAF 74/163 reads (45%) | catalogued as rs1279337096; ClinVar: likely benign; called by muse, mutect2, varscan2
- R3HCC1 | c.552C>G p.R184= (on ENST00000411463; = p.R144= on NM_001136108.3) | Silent (SNP) | VAF 122/314 reads (39%) | called by muse, mutect2, varscan2
- SPATS1 | c.543G>T p.T181= | Silent (SNP) | VAF 91/300 reads (30%) | called by muse, mutect2, varscan2
- TTN | c.27081C>T p.S9027= (on ENST00000591111; = p.S8100= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 31/228 reads (14%) | called by muse, mutect2, varscan2
- USP11 | c.2832C>T p.G944= (on ENST00000218348; = p.G901= on NM_001371072.1) | Silent (SNP) | VAF 22/183 reads (12%) | catalogued as rs751944013; called by muse, mutect2, varscan2
- ABHD12B | c.-35C>A | 5'UTR (SNP) | VAF 15/108 reads (14%) | called by muse, mutect2, varscan2
- ANK1 | c.5619+340G>A | Intron (SNP) | VAF 69/464 reads (15%) | catalogued as rs759611653; called by muse, mutect2, varscan2
- C10orf143 | c.69+3584G>C | Intron (SNP) | VAF 46/239 reads (19%) | called by muse, mutect2, varscan2
- DDX3X | c.45+373del | Intron (DEL) | VAF 22/200 reads (11%) | called by mutect2, varscan2
- IDNK | c.-25G>A | 5'UTR (SNP) | VAF 6/84 reads (7%) | called by muse, mutect2
- IFNGR1 | c.-41G>T | 5'UTR (SNP) | VAF 108/361 reads (30%) | called by muse, mutect2, varscan2
- IL10RA | c.*1087G>A | 3'UTR (SNP) | VAF 81/288 reads (28%) | catalogued as rs1323086949; called by muse, mutect2, varscan2
- LDB3 | c.689+3890C>T | Intron (SNP) | VAF 18/570 reads (3%) | called by muse, mutect2
- MCF2L | c.3165+334G>A | Intron (SNP) | VAF 44/293 reads (15%) | catalogued as rs766184913; called by muse, mutect2, varscan2
- OR2W5 | n.823C>T | RNA (SNP) | VAF 39/550 reads (7%) | catalogued as rs763106117; called by muse, mutect2
- PATZ1 | c.1335+1321T>C | Intron (SNP) | VAF 27/236 reads (11%) | called by muse, mutect2, varscan2
- PRICKLE3 | c.43-158C>A | Intron (SNP) | VAF 48/490 reads (10%) | called by muse, mutect2
- SLC2A11 | c.21+1124G>A | Intron (SNP) | VAF 14/156 reads (9%) | called by muse, mutect2
- TCTN1 | c.624+28C>T | Intron (SNP) | VAF 5/90 reads (6%) | catalogued as COSV100886217; called by muse, mutect2
- TRAV3 | c.-25G>A | 5'UTR (SNP) | VAF 28/237 reads (12%) | catalogued as rs933278307; called by muse, mutect2, varscan2
